Somatic mutation profile of cancer-model specimen HCM-WCMC-0502-C15-85A (3D Organoid, passage 11; aliquot HCM-WCMC-0502-C15-85A-01D-A83U-36), derived from the primary tumor of HCMI case HCM-WCMC-0502-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.9 years (15,658 days).
Specimen HCM-WCMC-0502-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81a8309f-58b7-4805-856e-869ff5acab50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0502-C15-10A (Blood Derived Normal), aliquot HCM-WCMC-0502-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c65d4b58-e0e9-4235-a5b6-57fbfab4cb33

The open-access MAF lists 155 somatic variants for this specimen: 119 protein-altering or splice-affecting, 30 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 30, Intron 4, Nonsense Mutation 4, Splice Region 1, 3'UTR 1, 5'Flank 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.83_100del p.V28_E33del | In Frame Del (DEL) | VAF 495/536 reads (92%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 168/168 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 392/392 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.50737C>T p.R16913* (on ENST00000591111; = p.R9489* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 221/638 reads (35%) | catalogued as rs1483931960, COSV59888643; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTC1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 298/300 reads (99%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.538); catalogued as rs866147243; called by muse, mutect2, varscan2
- ADAMTS5 | c.1715C>A p.S572Y | Missense Mutation (SNP) | VAF 147/341 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53185936; called by muse, mutect2, varscan2
- CKAP5 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 153/528 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1326516110, COSV56367217; called by muse, mutect2, varscan2
- CLC | c.385del p.D129Ifs*4 | Frame Shift Del (DEL) | VAF 115/313 reads (37%) | catalogued as COSV55686288; called by mutect2, pindel, varscan2
- CLEC4F | c.1616G>C p.R539P | Missense Mutation (SNP) | VAF 137/655 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs139353507; called by muse, mutect2, varscan2
- DAAM1 | c.1250A>T p.D417V | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV62840209; called by muse, mutect2, varscan2
- DNAH3 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 114/268 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.204); catalogued as COSV54511759, COSV99770890; called by muse, mutect2, varscan2
- ERI1 | c.317T>G p.L106R | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99141274; called by muse, mutect2, varscan2
- FLI1 | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 266/572 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55644399; called by muse, mutect2, varscan2
- LAMA2 | c.4661G>A p.G1554E | Missense Mutation (SNP) | VAF 40/501 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760072728; called by muse, mutect2
- MAP3K2 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 98/207 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs1283539905, COSV61294125; called by mutect2, varscan2
- MAP4K4 | c.2336A>G p.D779G (on ENST00000347699 / NM_001242559.2; = p.D697G on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 184/677 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.706); catalogued as rs947540335; called by muse, mutect2, varscan2
- MINPP1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 391/619 reads (63%) | catalogued as rs1339940985, COSV64355228; called by muse, mutect2, varscan2
- MPDZ | c.1155A>C p.Q385H | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV59947262; called by muse, mutect2
- PCDHA1 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 357/357 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs782599305, COSV65373425; called by muse, mutect2, varscan2
- PIEZO2 | c.6556G>A p.V2186M | Missense Mutation (SNP) | VAF 185/691 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs551918181; called by muse, mutect2, varscan2
- PIK3CG | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 296/610 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100783114, COSV63245916; called by muse, mutect2, varscan2
- PTPN6 | c.584A>G p.K195R | Missense Mutation (SNP) | VAF 162/384 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV59684876; called by muse, mutect2, varscan2
- RPL3L | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 255/535 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51906404; called by muse, mutect2, varscan2
- SAMD9L | c.3097C>A p.H1033N | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs1346650430, COSV59080940; called by muse, mutect2
- SETD5 | c.2705A>G p.N902S | Missense Mutation (SNP) | VAF 141/371 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs375109664; called by muse, mutect2, varscan2
- SLC22A14 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 173/354 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.029); catalogued as rs767352284; called by muse, mutect2, varscan2
- TRRAP | c.7790A>G p.K2597R (on ENST00000359863 / NM_001244580.1; = p.K2579R on NM_003496.3) | Missense Mutation (SNP) | VAF 165/369 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100723312; called by muse, mutect2, varscan2
- TTN | c.99623A>C p.E33208A (on ENST00000591111; = p.E25784A on NM_003319.4) | Missense Mutation (SNP) | VAF 230/655 reads (35%) | PolyPhen possibly damaging (0.616); catalogued as rs1553487855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UCMA | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 322/322 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs372826471; called by muse, mutect2, varscan2
- YWHAG | c.241A>G p.M81V | Missense Mutation (SNP) | VAF 262/567 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as rs1439613878; called by muse, mutect2, varscan2
- ZNF423 | c.272C>A p.T91K (on ENST00000563137 / NM_001379286.1; = p.T83K on NM_015069.4) | Missense Mutation (SNP) | VAF 157/303 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV52181840; called by muse, mutect2, varscan2
- ZNF697 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 102/479 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV70284263; called by muse, mutect2, varscan2
- ZSCAN25 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 208/477 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.972); catalogued as rs1458033031; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2559+4A>G | Splice Region (SNP) | VAF 381/644 reads (59%) | called by muse, mutect2, varscan2
- AFTPH | c.1527A>C p.E509D | Missense Mutation (SNP) | VAF 300/699 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AKR1B15 | c.641A>T p.E214V | Missense Mutation (SNP) | VAF 149/349 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANK1 | c.2535T>G p.D845E | Missense Mutation (SNP) | VAF 162/588 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ANKFN1 | c.1538A>C p.K513T | Missense Mutation (SNP) | VAF 157/477 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- AP002512.3 | c.473T>G p.L158R | Missense Mutation (SNP) | VAF 192/395 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF6 | c.1751_1761delinsCCCTTCTCCCC p.Q584_K587delinsPLLP | Missense Mutation (ONP) | VAF 19/207 reads (9%) | called by mutect2*, pindel
- ATP10B | c.3932T>C p.L1311P | Missense Mutation (SNP) | VAF 148/308 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- BSN | c.8064C>G p.I2688M | Missense Mutation (SNP) | VAF 284/532 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C20orf141 | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 277/554 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- CAPN10 | c.322T>A p.S108T | Missense Mutation (SNP) | VAF 347/580 reads (60%) | SIFT tolerated (0.39); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CHD7 | c.8434T>G p.L2812V | Missense Mutation (SNP) | VAF 224/894 reads (25%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- COL5A1 | c.1616T>G p.V539G | Missense Mutation (SNP) | VAF 232/746 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CSF2RA | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSF3R | c.1513A>C p.T505P | Missense Mutation (SNP) | VAF 258/431 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- DGKH | c.1456A>C p.T486P | Missense Mutation (SNP) | VAF 167/297 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- DSTYK | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 165/455 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECE1 | c.2304A>T p.E768D | Missense Mutation (SNP) | VAF 229/414 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ERGIC1 | c.388T>G p.F130V | Missense Mutation (SNP) | VAF 149/353 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ERVV-1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 168/1038 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, varscan2
- FOXD3 | c.1232G>C p.S411T | Missense Mutation (SNP) | VAF 357/966 reads (37%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAZ | c.670T>G p.F224V | Missense Mutation (SNP) | VAF 212/495 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- GOLGA8H | c.1738A>T p.S580C | Missense Mutation (SNP) | VAF 166/481 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- GOT2 | c.1187A>T p.K396M | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- GRIN2B | c.1623C>A p.S541R | Missense Mutation (SNP) | VAF 131/287 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HIVEP3 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 441/730 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- IPMK | c.751A>C p.S251R | Missense Mutation (SNP) | VAF 157/460 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KEAP1 | c.269C>G p.A90G | Missense Mutation (SNP) | VAF 337/706 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- LAMC2 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 284/484 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- LRRC8C | c.1055A>G p.E352G | Missense Mutation (SNP) | VAF 229/388 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- LRRCC1 | c.2389G>C p.E797Q | Missense Mutation (SNP) | VAF 85/444 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MAP4 | c.939A>C p.E313D | Missense Mutation (SNP) | VAF 176/397 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MPDZ | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- NBEA | c.2488C>T p.H830Y | Missense Mutation (SNP) | VAF 132/437 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NBPF1 | c.1023G>C p.M341I | Missense Mutation (SNP) | VAF 88/1176 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- NELL1 | c.1228T>C p.W410R | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- NIPSNAP1 | c.572A>C p.K191T | Missense Mutation (SNP) | VAF 170/332 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NLRP13 | c.2189A>G p.E730G | Missense Mutation (SNP) | VAF 195/1020 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- NR5A1 | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 411/695 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRAP | c.2015A>C p.K672T (on ENST00000359988 / NM_001322945.2; = p.K637T on NM_006175.4) | Missense Mutation (SNP) | VAF 123/448 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- NYAP2 | c.1694A>C p.H565P | Missense Mutation (SNP) | VAF 293/500 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR13C5 | c.409A>C p.S137R | Missense Mutation (SNP) | VAF 184/554 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- OR6C74 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 25/512 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OVCH1 | c.1685G>C p.G562A | Missense Mutation (SNP) | VAF 74/601 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P2RX2 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 189/670 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PACS1 | c.1187A>C p.K396T | Missense Mutation (SNP) | VAF 148/309 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PKD2 | c.1765A>T p.T589S | Missense Mutation (SNP) | VAF 172/334 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PKD2L1 | c.1856A>C p.E619A | Missense Mutation (SNP) | VAF 142/492 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PPM1F | c.737C>G p.A246G | Missense Mutation (SNP) | VAF 157/303 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PPP2R1A | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 277/1460 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAG1 | c.1333A>G p.R445G | Missense Mutation (SNP) | VAF 235/1599 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RARA | c.79T>G p.F27V | Missense Mutation (SNP) | VAF 322/1089 reads (30%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RASGEF1A | c.967A>C p.S323R | Missense Mutation (SNP) | VAF 151/347 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- RGL1 | c.120A>T p.K40N (on ENST00000360851 / NM_001297672.2; = p.K75N on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 231/391 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RNF213 | c.15425A>C p.K5142T | Missense Mutation (SNP) | VAF 192/584 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SCN8A | c.1404A>T p.E468D | Missense Mutation (SNP) | VAF 17/359 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- SFRP1 | c.341G>A p.C114Y | Missense Mutation (SNP) | VAF 289/918 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH2D4B | c.674G>T p.R225M | Missense Mutation (SNP) | VAF 218/677 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); called by muse, mutect2
- SIGLEC10 | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 76/1187 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0.031); called by muse, mutect2
- SIPA1L1 | c.5108A>C p.N1703T | Missense Mutation (SNP) | VAF 173/375 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- SLC36A2 | c.1004A>C p.N335T | Missense Mutation (SNP) | VAF 120/243 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- SORCS1 | c.2751A>C p.Q917H | Missense Mutation (SNP) | VAF 138/504 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPRR2E | c.4T>A p.S2T | Missense Mutation (SNP) | VAF 277/813 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SRBD1 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 185/348 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SRPX | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 162/169 reads (96%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- STARD8 | c.3038C>A p.T1013N | Missense Mutation (SNP) | VAF 214/215 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STON1 | c.1619A>C p.Y540S | Missense Mutation (SNP) | VAF 352/807 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2227T>A p.L743M | Missense Mutation (SNP) | VAF 102/390 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.19997T>G p.L6666R (on ENST00000367255 / NM_182961.4; = p.L6595R on NM_033071.3) | Missense Mutation (SNP) | VAF 167/385 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TMED2 | c.357A>T p.Q119H | Missense Mutation (SNP) | VAF 87/323 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMED5 | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 152/726 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- TMTC1 | c.1678T>G p.S560A (on ENST00000539277 / NM_001193451.2; = p.S452A on NM_175861.3) | Missense Mutation (SNP) | VAF 115/554 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- TNFRSF11B | c.818A>C p.D273A | Missense Mutation (SNP) | VAF 102/703 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TPRX1 | c.514T>G p.S172A | Missense Mutation (SNP) | VAF 326/698 reads (47%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, varscan2
- TRBC2 | c.368C>G p.A123G | Missense Mutation (SNP) | VAF 88/95 reads (93%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- TRIM39 | c.835T>G p.S279A | Missense Mutation (SNP) | VAF 147/325 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPV4 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 210/597 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TTN | c.69346A>T p.K23116* (on ENST00000591111; = p.K15692* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 316/504 reads (63%) | called by muse, mutect2, varscan2
- UBC | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 312/525 reads (59%) | called by muse, mutect2, varscan2
- UNC13C | c.3960T>A p.S1320R | Missense Mutation (SNP) | VAF 40/468 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- VIRMA | c.1283T>A p.L428H | Missense Mutation (SNP) | VAF 163/858 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- WDFY4 | c.9314A>C p.K3105T | Missense Mutation (SNP) | VAF 133/532 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- XIRP2 | c.2500A>T p.I834F (on ENST00000628543; = p.I1009F on NM_152381.6) | Missense Mutation (SNP) | VAF 168/518 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZNF600 | c.1387A>T p.I463F | Missense Mutation (SNP) | VAF 163/1023 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ZNF829 | c.946A>G p.R316G | Missense Mutation (SNP) | VAF 133/344 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- ZNF93 | c.773A>C p.K258T | Missense Mutation (SNP) | VAF 150/855 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCA8 | c.2742T>G p.S914= | Silent (SNP) | VAF 150/509 reads (29%) | called by muse, mutect2, varscan2
- ANTKMT | c.261C>T p.G87= | Silent (SNP) | VAF 207/449 reads (46%) | called by muse, mutect2, varscan2
- ATP2B4 | c.3549G>T p.A1183= | Silent (SNP) | VAF 24/606 reads (4%) | called by muse, mutect2
- CADM2 | c.519A>G p.K173= (on ENST00000407528 / NM_001167674.2; = p.K175= on NM_153184.4) | Silent (SNP) | VAF 107/472 reads (23%) | called by muse, mutect2, varscan2
- CCSER1 | c.507T>C p.T169= | Silent (SNP) | VAF 156/329 reads (47%) | called by muse, mutect2, varscan2
- CMYA5 | c.2370T>G p.R790= | Silent (SNP) | VAF 235/512 reads (46%) | called by muse, mutect2, varscan2
- CYP26C1 | c.834C>G p.G278= | Silent (SNP) | VAF 153/536 reads (29%) | called by muse, mutect2, varscan2
- DCDC2C | c.213G>A p.R71= | Silent (SNP) | VAF 58/1790 reads (3%) | catalogued as rs1345045111; called by muse, mutect2
- DEUP1 | c.24G>A p.T8= | Silent (SNP) | VAF 78/211 reads (37%) | catalogued as rs752444785, COSV53209745; called by muse, mutect2, varscan2
- DNAH3 | c.6787T>C p.L2263= | Silent (SNP) | VAF 157/384 reads (41%) | catalogued as rs148640490; called by muse, mutect2, varscan2
- ERICH6B | c.1014C>T p.S338= | Silent (SNP) | VAF 143/347 reads (41%) | catalogued as rs373426079, COSV100075257; called by muse, mutect2, varscan2
- GABRQ | c.513G>C p.V171= | Silent (SNP) | VAF 183/183 reads (100%) | catalogued as COSV64783957; called by muse, mutect2, varscan2
- GPR152 | c.1359A>G p.G453= | Silent (SNP) | VAF 237/510 reads (46%) | called by muse, mutect2, varscan2
- HCN4 | c.2652C>A p.P884= | Silent (SNP) | VAF 669/1070 reads (63%) | called by muse, mutect2, varscan2
- HIF1A | c.1260T>C p.T420= | Silent (SNP) | VAF 94/218 reads (43%) | catalogued as rs753493493; called by muse, mutect2, varscan2
- HNF1B | c.441G>A p.Q147= | Silent (SNP) | VAF 290/904 reads (32%) | called by muse, mutect2, varscan2
- IGFBP7 | c.231C>A p.G77= | Silent (SNP) | VAF 292/694 reads (42%) | called by muse, mutect2, varscan2
- LPIN1 | c.21A>G p.L7= | Silent (SNP) | VAF 171/700 reads (24%) | called by muse, mutect2, varscan2
- MAP3K21 | c.2587A>C p.R863= | Silent (SNP) | VAF 152/426 reads (36%) | called by muse, mutect2, varscan2
- MROH1 | c.3403C>T p.L1135= | Silent (SNP) | VAF 251/808 reads (31%) | called by muse, mutect2, varscan2
- NR4A1 | c.894C>T p.N298= | Silent (SNP) | VAF 232/233 reads (100%) | catalogued as rs768092406, COSV54482935; called by muse, mutect2, varscan2
- NXPH1 | c.157T>C p.L53= | Silent (SNP) | VAF 224/445 reads (50%) | catalogued as COSV101339701, COSV68318636; called by muse, mutect2, varscan2
- PALB2 | c.1426A>C p.R476= | Silent (SNP) | VAF 197/470 reads (42%) | called by muse, mutect2, varscan2
- PAM | c.1818T>C p.D606= | Silent (SNP) | VAF 224/224 reads (100%) | called by muse, mutect2, varscan2
- POC1B | c.1107T>C p.S369= | Silent (SNP) | VAF 42/44 reads (95%) | called by muse, mutect2, varscan2
- PRB2 | c.1119A>G p.E373= | Silent (SNP) | VAF 297/727 reads (41%) | called by muse, mutect2, varscan2
- PRSS57 | c.225C>T p.C75= | Silent (SNP) | VAF 192/429 reads (45%) | catalogued as rs767532063; called by muse, mutect2, varscan2
- PTGER1 | c.960C>T p.A320= | Silent (SNP) | VAF 56/402 reads (14%) | called by muse, mutect2, varscan2
- RNF31 | c.1587C>T p.P529= | Silent (SNP) | VAF 45/617 reads (7%) | called by muse, mutect2
- RP1 | c.5193C>A p.I1731= | Silent (SNP) | VAF 18/587 reads (3%) | catalogued as COSV55120805; called by muse, mutect2
- DCAF13 | chr8:103415224 C>G | 5'Flank (SNP) | VAF 254/1103 reads (23%) | called by muse, mutect2, varscan2
- FAM104A | c.322-2933A>C | Intron (SNP) | VAF 122/458 reads (27%) | called by muse, mutect2, varscan2
- LEKR1 | c.*1532T>C | 3'UTR (SNP) | VAF 112/415 reads (27%) | catalogued as rs1232095865; called by muse, mutect2, varscan2
- PLCH2 | c.2959+159C>A | Intron (SNP) | VAF 392/1091 reads (36%) | called by muse, mutect2, varscan2
- PML | c.1710+1402C>G | Intron (SNP) | VAF 272/975 reads (28%) | catalogued as rs761737205; called by muse, mutect2, varscan2
- RPS29 | c.162+40G>A | Intron (SNP) | VAF 478/478 reads (100%) | called by muse, mutect2, varscan2
